Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8IB, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8IB-01A (Primary Tumor).

[page 1 of 5]
Specimen Date/Time: 12/27/2012

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT OBTURATOR AND EXTERNAL ILIAC LYMPH NODES:
Four lymph nodes, no tumor present (0/4).
(B) LEFT HYPOGASTRIC LYMPH NODES:
Two lymph nodes, no tumor present (0/2).
(C) RIGHT OBTURATOR AND EXTERNAL ILIAC LYMPH NODES:
Seven lymph nodes, no tumor present (0/7).
(D) RIGHT HYPOGASTRIC LYMPH NODES:
Eight lymph nodes, no tumor present (0/8).
(E) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

OK ICD-0-3
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site Prostate NOS 61.9
JW 11/24/13

Entire report and diagnosis completed by Patricia Troncoso MD 896

PT:JH/msm
DD: 12/31/12
12/31/2012 5:44 PM

GROSS DESCRIPTION

- (A) LEFT OBTURATOR AND EXTERNAL ILIAC LYMPH NODES – A fragment of tan-yellow soft tissue (4.0 x 3.5 x 2.0 cm, overall), dissected for nodes. Four possible lymph nodes are identified ranging in size from 0.9-3.0 cm.
SECTION CODE: A1-A2, single serially sectioned node; A3-A4, single serially sectioned node; A5-A6, single serially sectioned node; A7, single bisected node. DA1/jfj
(B) LEFT HYPOGASTRIC LYMPH NODES – A fragment of tan-yellow soft tissue (2.0 x 1.0 x 0.5 cm overall). No definite lymph nodes are identified and the tissue is entirely submitted in two cassettes, B1-B2. DA1/jfj:JH/msm
(C) RIGHT OBTURATOR AND EXTERNAL ILIAC LYMPH NODES – An irregular portion of tan-yellow soft tissue (3.9 x 2.0 x 2.0 cm, overall), dissected for lymph nodes and multiple lymph nodes identified ranging in size from 0.5-3.0 cm.
SECTION CODE: C1-C2, single serially sectioned node; C3, three possible nodes; C4-C5, single serially sectioned node. DA1/jfj
(D) RIGHT HYPOGASTRIC LYMPH NODES – A 3.2 x 2.1 x 0.8 cm aggregate of fibroadipose tissue. Three possible lymph nodes are grossly identified ranging from 0.2 x 0.2 x 0.2 cm to 1.2 x 0.4 x 0.4 cm. The specimen is submitted entirely.
SECTION CODE: D1, two possible lymph nodes; D2, one possible lymph node serially sectioned; D3, remaining fibroadipose tissue. SJ/jfj:JH/msm
(E) PROSTATE AND SEMINAL VESICLES – A supplemental report to follow. PT/msm

BIOMARKER TESTING

CLINICAL HISTORY

Prostate cancer.

SNOMED CODES

T-C4600, M-00110

"Some tests reported here may have been developed and performance characteristics determined by UT MD Anderson Pathology and Laboratory Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by: Patricia Troncoso MD 896 Jan 04, 2013

[page 2 of 5]
[REDACTED] [REDACTED]
Specimen Date/Time: 12/27/2012

Start of ADDENDUM

[page 3 of 5]
Specimen Date/Time: 12/27/2012

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by Troncoso, Patricia MD.
Jan 24, 2013 at 11:00 AM

DIAGNOSIS

- (E) PROSTATE AND SEMINAL VESICLES:
PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4+5). (SEE COMMENT)
MULTIFOCAL EXTRAPROSTATIC EXTENSION.
MICROSCOPIC BLADDER NECK INVASION PRESENT.
MARGINS OF RESECTION, FREE OF TUMOR.
Bilateral seminal vesicles and vasa deferentia, free of tumor.
PERINEURAL INVASION PRESENT.
LYMPHOVASCULAR INVASION PRESENT.
HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA PRESENT.

COMMENT

The prostate gland contains three tumor foci, one in the peripheral zone and two in the transition zone. The dominant tumor focus is considered of peripheral zone origin. This tumor focus involves predominantly the right side the prostate. The tumor involves the right posterolateral, right lateral, right anterolateral, right anterior, mid anterior, left anterior, left anterolateral, left lateral and left posterolateral peripheral zone with extension into the right and left transition zone. This tumor focus measures 3.9 x 2.4 cm in the largest cross-sectional dimension and it involves the three cross sections of the prostate, and extensively the apex and base. The tumor extends into extraprostatic tissue at multiple sites including the left apex, right anterolateral surface, right base. The added length of extraprostatic extension is 3.0 mm. The tumor invades at the base of the prostate thick smooth muscle bundles consistent with microscopic bladder neck invasion. It should be noted that microscopic bladder neck invasion is considered pT3a. The margins of resection are free of tumor.

The second tumor focus is located in the left transition zone. This tumor focus measures 1.5 x 0.2 cm in greatest cross-sectional dimension, and involves one cross section of the prostate, and focally the base. The third tumor focus is located in the left transition zone, exclusively in the apex. This tumor focus measures 0.4 x 0.2 cm in largest cross sectional dimension, and it is present in one apical section. The non-dominant tumor foci are of lower histologic grade and are confined to the prostate with negative margins.

Immunohistochemical stains with ERG (E27, E43, E49) are negative. These results are non-contributory towards supporting multiple tumor foci of different zonal origin.

PT/JH/rgw
DD: 1/24/13
1/24/2013 11:16 AM

GROSS DESCRIPTION

(E) PROSTATE AND SEMINAL VESICLES - A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (4.5 x 3.0 x 4.2 cm, 48.0 grams, post-fixation) has the usual shape. The soft tissue present along the

[page 4 of 5]
Specimen Date/Time: 12/27/2012

right posterolateral aspect of the prostate appears more abundant than along the left side. Serial cross sections after fixation demonstrate an area consistent with tumor within the right side of the three cross sections of the prostate. The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: E1-E3, right seminal vesicle and vas deferens entirely submitted from base-to-tip; E4, E5, left seminal vesicle and vas deferens entirely submitted from base-to-tip; E6-E8, prostatic base right border; E9-E12, prostatic base right posterior border; E13-E18, prostatic base central portion; E19, E20, prostatic base left border; E21-E23, prostatic base left posterior border; E24, E25, apex anterior; E26, E27, apex left; E28-E33, apex posterior; E34, E35, apex right; E36, detached portions of margin of resection according to specimen radiograph; E37-E54, sections of the three cross sections of the prostate according to specimen radiograph.

INK CODE: The anterior aspect of the prostate is green, left surface in red, right surface in yellow and posterior surface in black. Orange ink (E59, 53) denotes surfaces that do not represent the true margin of resection. JH/rgw

SNOMED CODES

T-92000; M-Y1973

Entire report and diagnosis completed by: Patricia Troncoso MD 896 Feb 04, 2013

-----END OF REPORT-----

Division of Pathology and Laboratory Medicine
U.T.M.D. Anderson Cancer Center
1515 Holcombe Boulevard
Houston, Texas 77030

[page 5 of 5]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): MD ANDERSON TSS Identifier: KK TSS Unique Patient Identifier: KK-1046
Completed By (Interviewer Name on OpenClinica): DAVID KENNEDY Completed Date: 7-NOV-2013

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	4 + 5 = 9	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	4 + 4 = 8	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The Gleason score initially submitted and reviewed on the top slide is not consistent with the Gleason score that is listed on the pathology report from the prostatectomy	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	Dr. Troncoso	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

11/7/13
Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

11/7/13
Date

Source: NCI Genomic Data Commons file e3dcf2cf-fdd4-4830-94e3-d47595c1f2cc (TCGA-KK-A8IB.B9FBCA1B-CAEB-48A1-87B8-C873AC07FD8B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).